Somatic mutation profile of tumor specimen 0DBXXX from CCDI case PBBLMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,088 days).
Specimen 0DBXXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 956ebc76-d1ff-479b-b4e0-78bb071e0ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBXXU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d59d105-dc63-4cba-8d7f-cf03a7812fa0

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 5'UTR 2, 3'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R6 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 43/537 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs1172027492; called by muse, mutect2
- PPP1R1A | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.229); catalogued as COSV54494137; called by muse, mutect2, varscan2
- RTTN | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 221/826 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs376633925; called by muse, mutect2, varscan2
- CILP2 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX50 | c.271_275del p.S91Kfs*11 | Frame Shift Del (DEL) | VAF 144/488 reads (30%) | called by mutect2, varscan2
- IFNA4 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as rs1167537044; called by muse, mutect2
- MROH2B | c.2847G>A p.A949= | Silent (SNP) | VAF 322/850 reads (38%) | catalogued as rs371233888; called by muse, mutect2, varscan2
- SLC4A5 | c.237C>T p.S79= | Silent (SNP) | VAF 61/341 reads (18%) | called by muse, mutect2, varscan2
- ENPP4 | c.-3dup | 5'UTR (INS) | VAF 56/309 reads (18%) | called by mutect2, varscan2
- OSGIN1 | n.1355C>T | RNA (SNP) | VAF 62/236 reads (26%) | catalogued as rs772430274, COSV100533953; called by muse, mutect2, varscan2
- RC3H2 | c.*74T>C | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
